Surgical pathology report (de-identified scan), TCGA case TCGA-EV-5901, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site CHI-Penrose Colorado, specimen TCGA-EV-5901-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

SPECIMEN

A. KIDNEY - 1. Left kidney mass (margin measurements) Genome project 1243 p.m.

CLINICAL INFORMATION

Left kidney mass.

GROSS DESCRIPTION

The specimen is received fresh in frozen section room labeled with the patient's name [REDACTED] and additionally labeled "left kidney mass" and consists of a 4.5 x 3.1 x 3 cm fragment of kidney covered by adipose tissue, measuring 7 x 3.5 x 1 cm. There is a 2.4 cm in maximal diameter tan lobulated mass, which is located 0.5 cm from the surgical margin. The surgical kidney margin is inked black and the renal capsule is inked red. A representative section is submitted for frozen section interpretation [REDACTED]. The frozen section residual is submitted in cassette (A1). The remainder of the lesion is submitted in cassettes (A2)-(A6).

Frozen section diagnosis:

FSA1 - "Primary renal neoplasm. Margin negative, 0.5 cm from tumor."

MICROSCOPIC DESCRIPTION

The frozen section diagnosis is confirmed. The primary renal neoplasm is a type 2 papillary renal cell carcinoma, Fuhrman nuclear grade 3. The tumor is confined to the kidney with a predominately pseudo solid appearance due to compression of papillae and tubules. Aggregates of foamy macrophages and focal areas of papillae with fibrovascular cores and scattered psammoma bodies are present. The tumor has a somewhat biphasic appearance with an admixture of cells with round, more uniform nuclei and scant cytoplasm and cells with enlarged, irregular nuclei with focally prominent nucleoli and moderate amounts of eosinophilic cytoplasm. The tumor is 0.55 cm from the kidney margin and does not penetrate the renal capsule. Mild arteriosclerosis is seen in the adjacent uninvolved kidney.

[page 2 of 2]
SPECIMEN TYPE: Left partial nephrectomy.

TUMOR SIZE: 2.4 cm.

MACROSCOPIC EXTENT OF TUMOR: Limited to kidney.

HISTOLOGIC TYPE: Papillary renal carcinoma.

HISTOLOGIC GRADE: G3.

EXTENT OF INVASION: T1.

MARGINS: Margins uninvolved by tumor (0.55 cm from kidney margin).

BLOOD/LYMPHATIC VESSEL INVASION: Absent.

REGIONAL LYMPH NODES: NX.

DISTANT METASTASIS: MX.

ADDITIONAL PATHOLOGIC FINDINGS: Mild arteriosclerosis.

FINAL DIAGNOSIS

KIDNEY, LEFT, PARTIAL NEPHRECTOMY

- Papillary renal cell carcinoma.
- Tumor size 2.4 cm.
- Fuhrman nuclear grade 3.
- Surgical margins negative.
- Mild arteriosclerosis.

CPT CODE(S): 88307x1, 88331x1

Source: NCI Genomic Data Commons file 25d7b0a1-cb8c-4320-a8ae-27ad88cb9d35 (TCGA-EV-5901.150D2876-A5A9-4075-93A3-92CB37043129.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).